Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5195, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5195-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

TCGA-BP-5195

Clinical Diagnosis & History:

Incidental 3 cm left upper pole renal mass.

Specimens Submitted:

1: Kidney, Left Upper Pole; Partial Nephrectomy ✓

DIAGNOSIS:

1. Kidney, Left Upper Pole; Partial Nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 2.4 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

shows focal chronic inflammation and focal superficial glomerulosclerosis ✓

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor $\leq$ 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh for frozen section consultation, labeled "left upper pole renal tumor stitch marks deep margin". It consists of a 6.6 x 3.7 x 2.9 cm wedge shaped portion of kidney with a suture marking the deep margin and attached 12.2 x 8.5 x 2.7 cm of perirenal. Also received in the same container is a separate 11.6 x 8.4 x 4.6 cm aggregate of unremarkable fibroadipose tissue. The margin is inked black and the specimen is serially sectioned to reveal a well-circumscribed cortically based yellow focally hemorrhagic 2.4 x 2.0 x 1.9 cm tumor. The tumor appears grossly confined to the renal parenchyma, no extension into perirenal fat is identified. The clearance from the resection margin is 1.1 cm. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. A photograph is taken. Portions of the tumor are submitted for TPS.

Summary of sections:

FSC - frozen section control

T - tumor

M - margin

RS - representative sections

Summary of Sections:

Part 1: Kidney, Left Upper Pole; Partial Nephrectomy

Block	Sect. Site	PCs
1	fsc	1
2	m	2
1	rs	1
2	t	2

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: LEFT UPPER POLE RENAL TUMOR (). RENAL CORTICAL NEOPLASM WITH BENIGN MARGIN. ()
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file bb892f21-8c58-4775-954c-8f4ffc0dead9 (TCGA-BP-5195.25C0B433-5557-4165-922E-2C1EAC9C26F0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).